Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAF3, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAF3-01A (Primary Tumor).

Department of Pathology

ICD O3
Seminoma NOS 9061/3
Site @ Testis NOS C62.9
JW 2/13/14

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Summary pathology report

Left orchidectomy; seminoma; diameter 5 cm; tumor confined to testis in available slides; no angio-invasion present; invasion in rete testis present.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 38d699ae-0e34-4953-bb0e-1d3f51ab2e45 (TCGA-2G-AAF3-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).